Somatic mutation profile of tumor specimen TARGET-10-PANVCM-09A (aliquot TARGET-10-PANVCM-09A-01D) from TARGET case TARGET-10-PANVCM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (588 days).
Specimen TARGET-10-PANVCM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14e90ee4-d605-4aa2-8509-42123645ed1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVCM-14A (Bone Marrow Normal), aliquot TARGET-10-PANVCM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4a0a7e2-b450-431a-83de-bec3b9efb3a5

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNGB1 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs775590206; called by muse, mutect2, varscan2
- PLXDC2 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.148); catalogued as rs775360529, COSV65902218; called by muse, mutect2, varscan2
- FMO4 | c.261T>A p.F87L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NAP1L3 | c.721T>G p.C241G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCQ | c.1281_1282insT p.E428* | Frame Shift Ins (INS) | VAF 13/122 reads (11%) | called by mutect2, pindel, varscan2
- LRIG2 | c.2295C>A p.T765= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100743547; called by muse, mutect2, varscan2
- OTOP1 | c.1800C>T p.H600= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs375899210; called by muse, mutect2, varscan2
